Somatic mutation profile of tumor specimen ALCH-B2T8-TTP1-A (aliquot ALCH-B2T8-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2T8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.5 years (19,524 days).
Specimen ALCH-B2T8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df65e035-329e-42ee-921a-13b4f5260ca6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2T8-NB1-A (Blood Derived Normal), aliquot ALCH-B2T8-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1df366d8-2c79-4f75-98c5-af775f8de71e

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 4, Intron 3, 3'UTR 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 20/84 reads (24%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AFF2 | c.2711C>A p.A904E | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.425); catalogued as COSV53979204; called by muse, mutect2
- ANO5 | c.1685T>A p.L562Q | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100201902; called by muse, mutect2, varscan2
- CAMK2A | c.1369C>T p.R457C (on ENST00000348628 / NM_171825.2; = p.R468C on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/484 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs754732557; called by muse, mutect2
- CDH7 | c.2024A>G p.N675S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.622); catalogued as rs775884204; called by mutect2, varscan2
- CUL9 | c.7201C>T p.R2401W | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs943334996; called by muse, mutect2, varscan2
- EOGT | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as rs376499113; called by muse, mutect2, varscan2
- KLHL34 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs1428098515; called by muse, mutect2, varscan2
- LLGL2 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745709991, COSV51384058; called by muse, mutect2, varscan2
- PCDHGA11 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV53991735; called by muse, mutect2, varscan2
- PRDM1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317146603, COSV64844219; called by muse, mutect2, varscan2
- PRKG1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 53/573 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV64872543; called by muse, mutect2
- RIPK1 | c.1927G>T p.G643* | Nonsense Mutation (SNP) | VAF 59/216 reads (27%) | catalogued as COSV99455037; called by muse, mutect2, varscan2
- SEMA5A | c.2936C>A p.S979Y | Missense Mutation (SNP) | VAF 34/700 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV66801194; called by muse, mutect2
- CDH18 | c.545C>A p.T182K | Missense Mutation (SNP) | VAF 176/246 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CDKL5 | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLIP1 | c.1214A>C p.E405A | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- FOXO4 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIPAP1 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- HMCN2 | c.11116C>T p.P3706S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- MCM9 | c.3029C>T p.A1010V | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); called by muse, mutect2
- MOGAT1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- MOSPD2 | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO10 | c.4997A>G p.E1666G | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.639); called by muse, mutect2
- NEUROD1 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.066); called by muse, mutect2
- PITX2 | c.799C>T p.P267S (on ENST00000354925 / NM_001204397.1; = p.P274S on NM_000325.6) | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2
- SERPINA1 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 28/274 reads (10%) | called by muse, mutect2
- SH3D21 | c.2178G>C p.K726N (on ENST00000453908 / NM_001162530.2; = p.K615N on NM_024676.5) | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SPATA32 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2
- TMEM205 | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, varscan2
- UNC5C | c.491-2A>C p.X164_splice | Splice Site (SNP) | VAF 51/203 reads (25%) | called by muse, mutect2, varscan2
- VPS13C | c.686C>T p.T229I (on ENST00000644861 / NM_020821.3; = p.T186I on NM_017684.5) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- ZNF208 | c.3255C>A p.Y1085* | Nonsense Mutation (SNP) | VAF 14/299 reads (5%) | called by muse, mutect2
- ZNF532 | c.2875C>T p.H959Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF729 | c.871A>T p.T291S | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2
- CNGA2 | c.1173C>T p.A391= | Silent (SNP) | VAF 12/248 reads (5%) | catalogued as rs1453633113, COSV104395842; called by muse, mutect2
- DDX39B | c.1059C>A p.I353= | Silent (SNP) | VAF 16/408 reads (4%) | called by muse, mutect2
- KMT2D | c.10809G>A p.Q3603= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1555189181, COSV56409836; called by mutect2, varscan2
- MYH8 | c.3468C>T p.A1156= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as rs1308206260, COSV67964754; called by muse, mutect2
- PCDHB12 | c.183G>A p.S61= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs782166376, COSV53392772; called by muse, mutect2, varscan2
- PLXNA1 | c.1860C>T p.P620= | Silent (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2, varscan2
- TECTA | c.4878C>T p.N1626= | Silent (SNP) | VAF 18/276 reads (7%) | catalogued as rs151056317; called by muse, mutect2
- WDPCP | c.240G>A p.Q80= | Silent (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- ZNF831 | c.1785C>T p.A595= | Silent (SNP) | VAF 37/112 reads (33%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.703+66C>A | Intron (SNP) | VAF 16/197 reads (8%) | called by muse, mutect2
- F8 | c.*22C>A | 3'UTR (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- TNKS | c.673+40T>G | Intron (SNP) | VAF 36/110 reads (33%) | called by muse, varscan2
- VSTM2A | c.*79G>A | 3'UTR (SNP) | VAF 25/195 reads (13%) | catalogued as rs1354959945, COSV68289192; called by muse, mutect2, varscan2
- WDR45 | c.236-54G>C | Intron (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
